Somatic mutation profile of tumor specimen MP2PRT-PATFJE-TMP1-A (aliquot MP2PRT-PATFJE-TMP1-A-1-0-D-A81Y-36) from MP2PRT case MP2PRT-PATFJE, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 7.1 years (2,605 days).
Specimen MP2PRT-PATFJE-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6bfb099e-aba2-48c1-8aac-050317f5d7b2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PATFJE-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PATFJE-NB1-A-1-0-D-A81Y-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/26ea7b6f-8bc4-4e83-ace1-2125b493a361

The open-access MAF lists 34 somatic variants for this specimen: 25 protein-altering or splice-affecting, 9 silent.
By variant classification: Missense Mutation 22, Silent 9, Nonsense Mutation 2, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTPN11 | c.1529A>T p.Q510L | Missense Mutation (SNP) | VAF 108/363 reads (30%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as CM043070, CM052358, COSV61008620; called by muse, varscan2
- ANK3 | c.1078G>A p.V360M | Missense Mutation (SNP) | VAF 90/334 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs780148122; called by muse, mutect2, varscan2
- ANKUB1 | c.535C>T p.R179C | Missense Mutation (SNP) | VAF 40/241 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.017); catalogued as rs538883341, COSV67167993; called by muse, mutect2, varscan2
- BTBD17 | c.556G>T p.E186* | Nonsense Mutation (SNP) | VAF 48/923 reads (5%) | catalogued as COSV100945279; called by muse, mutect2
- CDH4 | c.2326G>A p.V776I | Missense Mutation (SNP) | VAF 18/326 reads (6%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.859); catalogued as rs142330895; called by muse, mutect2
- COL17A1 | c.446C>T p.A149V | Missense Mutation (SNP) | VAF 88/282 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.454); catalogued as rs757767776; called by muse, varscan2
- NPTXR | c.1102G>T p.A368S | Missense Mutation (SNP) | VAF 42/249 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.81); catalogued as COSV60728236; called by muse, mutect2, varscan2
- NRK | c.2621G>T p.G874V | Missense Mutation (SNP) | VAF 50/142 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV54596020; called by muse, varscan2
- PIP4K2B | c.311G>A p.R104Q | Missense Mutation (SNP) | VAF 84/460 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.557); catalogued as rs534790786; called by muse, mutect2, varscan2
- RTN4RL1 | c.340C>T p.R114W | Missense Mutation (SNP) | VAF 116/494 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs767452609; called by muse, varscan2
- RXFP3 | c.1297G>T p.A433S | Missense Mutation (SNP) | VAF 49/934 reads (5%) | SIFT tolerated (0.05); PolyPhen benign (0.015); catalogued as rs755392460; called by muse, mutect2
- ABCF2 | c.827G>A p.R276H | Missense Mutation (SNP) | VAF 35/179 reads (20%) | SIFT tolerated (0.21); PolyPhen benign (0.066); called by muse, mutect2, varscan2
- C9orf43 | c.129C>A p.C43* | Nonsense Mutation (SNP) | VAF 74/270 reads (27%) | called by muse, varscan2
- CSMD3 | c.2845C>G p.L949V (on ENST00000297405 / NM_001363185.1; = p.L845V on NM_052900.3) | Missense Mutation (SNP) | VAF 73/322 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- DNAH9 | c.8270G>A p.C2757Y | Missense Mutation (SNP) | VAF 101/469 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.827); called by muse, mutect2, varscan2
- EVX1 | c.988C>G p.P330A | Missense Mutation (SNP) | VAF 30/708 reads (4%) | SIFT tolerated (0.5); PolyPhen benign (0.006); called by muse, mutect2
- KCNA1 | c.1306G>T p.A436S | Missense Mutation (SNP) | VAF 109/389 reads (28%) | SIFT tolerated, low confidence (0.97); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- LRRC66 | c.1015G>T p.A339S | Missense Mutation (SNP) | VAF 116/513 reads (23%) | SIFT tolerated (0.34); PolyPhen benign (0.098); called by muse, mutect2, varscan2
- MEIS2 | c.1098G>T p.M366I (on ENST00000561208 / NM_170675.5; = p.M346I on NM_002399.3) | Missense Mutation (SNP) | VAF 38/415 reads (9%) | SIFT tolerated (0.11); PolyPhen benign (0.005); called by muse, mutect2
- MUC19 | c.433A>T p.T145S | Missense Mutation (SNP) | VAF 79/227 reads (35%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.695); called by muse, mutect2, varscan2
- NCAM2 | c.859G>T p.A287S | Missense Mutation (SNP) | VAF 53/575 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.765); called by muse, mutect2
- NHS | c.335C>T p.A112V | Missense Mutation (SNP) | VAF 162/384 reads (42%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.026); called by mutect2, varscan2
- PKNOX1 | c.271_278del p.V91Rfs*17 | Frame Shift Del (DEL) | VAF 62/635 reads (10%) | called by mutect2, pindel
- PRTFDC1 | c.386T>A p.L129H | Missense Mutation (SNP) | VAF 58/208 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- RPL26 | c.216G>T p.Q72H | Missense Mutation (SNP) | VAF 73/389 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.053); called by muse, mutect2, varscan2
- ADAM17 | c.1632C>T p.G544= | Silent (SNP) | VAF 75/245 reads (31%) | catalogued as rs754676488; ClinVar: likely benign; called by muse, mutect2, varscan2
- AL133500.1 | c.1143C>A p.P381= | Silent (SNP) | VAF 92/228 reads (40%) | catalogued as COSV55744553, COSV55744638; called by muse, mutect2, varscan2
- GPR12 | c.450G>A p.S150= | Silent (SNP) | VAF 87/286 reads (30%) | catalogued as rs772800273, COSV101198038, COSV67344432; called by muse, mutect2, varscan2
- GPR37 | c.600G>T p.T200= | Silent (SNP) | VAF 155/524 reads (30%) | catalogued as COSV58257209; called by muse, mutect2, varscan2
- HSPG2 | c.7314G>A p.T2438= | Silent (SNP) | VAF 96/346 reads (28%) | catalogued as rs745901454, COSV65976745; called by muse, mutect2
- IL13RA2 | c.435C>T p.C145= | Silent (SNP) | VAF 41/144 reads (28%) | catalogued as rs199528071, COSV54565300; called by muse, mutect2, varscan2
- PCDH15 | c.1224C>T p.A408= | Silent (SNP) | VAF 84/332 reads (25%) | called by muse, mutect2, varscan2
- SALL3 | c.2631C>T p.N877= | Silent (SNP) | VAF 197/672 reads (29%) | catalogued as rs367651872; called by muse, mutect2, varscan2
- STEAP1 | c.75C>T p.D25= | Silent (SNP) | VAF 14/80 reads (18%) | catalogued as rs750913817, COSV51881556, COSV51882548; called by muse, mutect2, varscan2
